Somatic mutation profile of tumor specimen TARGET-10-PARJMY-09A (aliquot TARGET-10-PARJMY-09A-01D) from TARGET case TARGET-10-PARJMY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.9 years (4,717 days).
Specimen TARGET-10-PARJMY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27e50934-5512-48a4-b7cb-7fbe86d655e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARJMY-10A (Blood Derived Normal), aliquot TARGET-10-PARJMY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d908792f-ffc9-4a55-a78c-6f5a24dcfb90

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CGN | c.3335G>A p.R1112H | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374749068; called by muse, mutect2, varscan2
- FAT1 | c.12035C>T p.T4012M | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs752997628, COSV71673299; called by muse, mutect2, varscan2
- PXDN | c.3776C>T p.P1259L | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs369587687, COSV99070649; called by muse, mutect2, varscan2
- ZNF582 | c.1016A>G p.Y339C | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1328731578; called by muse, mutect2, varscan2
- NBEA | c.6850A>G p.N2284D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AGAP2 | c.2857+20G>A | Intron (SNP) | VAF 19/47 reads (40%) | catalogued as rs746808977; called by muse, mutect2, varscan2
- DLX1 | c.513+566G>C | Intron (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2, varscan2
- SLC35B1 | c.216-26T>C | Intron (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
